Somatic mutation profile of tumor specimen MP2PRT-PASSZG-TBP1-A (aliquot MP2PRT-PASSZG-TBP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASSZG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (585 days).
Specimen MP2PRT-PASSZG-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65a5d50e-a448-4e99-a044-acd39872b60e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSZG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSZG-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f31b75b7-2fae-43b5-be53-57126e4e65b4

The open-access MAF lists 81 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 17, Nonsense Mutation 4, Splice Region 1, Intron 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730880471; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ANO3 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV56808340; called by muse, mutect2, varscan2
- CDC42BPA | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62014215; called by muse, mutect2, varscan2
- CEP57 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs562909477; called by muse, mutect2, varscan2
- CHM | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 80/331 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM920195, COSV63304160; called by muse, mutect2, varscan2
- CLDN15 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 128/476 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs776976484; called by muse, mutect2, varscan2
- CLIP2 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.045); catalogued as rs782013291; called by muse, mutect2, varscan2
- DDIAS | c.1294G>C p.E432Q | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs982496076; called by muse, mutect2, varscan2
- GABRA2 | c.1059+7G>A | Splice Region (SNP) | VAF 24/208 reads (12%) | catalogued as rs919561036; called by muse, varscan2
- HEXB | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs750645495, COSV54667173, COSV99784127; called by muse, mutect2, varscan2
- JAZF1 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 72/590 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV52239421; called by muse, mutect2, varscan2
- KPTN | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 120/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs372917020; called by muse, mutect2, varscan2
- MAOB | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV65204820; called by muse, mutect2, varscan2
- POU3F3 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 136/613 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796894; called by muse, mutect2, varscan2
- PREX2 | c.2852C>G p.S951* | Nonsense Mutation (SNP) | VAF 66/374 reads (18%) | catalogued as COSV99906691; called by muse, mutect2
- PRPF18 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 63/383 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60724984; called by muse, mutect2, varscan2
- SHLD2 | c.16C>G p.Q6E | Missense Mutation (SNP) | VAF 63/256 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV100079042; called by muse, mutect2, varscan2
- SLC35F3 | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 116/638 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.774); catalogued as rs145835583; called by muse, mutect2
- SLCO4C1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 81/299 reads (27%) | catalogued as rs144992469, COSV60512712; called by muse, mutect2, varscan2
- TFB2M | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 141/439 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV100829898, COSV63619742; called by muse, mutect2, varscan2
- TRPC3 | c.655G>A p.D219N (on ENST00000379645 / NM_001366479.2; = p.D146N on NM_003305.2) | Missense Mutation (SNP) | VAF 158/523 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868073711, COSV53371571; called by muse, mutect2, varscan2
- UNC13C | c.4930G>C p.E1644Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99522202; called by muse, mutect2, varscan2
- YBX3 | c.622G>C p.D208H | Missense Mutation (SNP) | VAF 78/485 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.62); catalogued as COSV99685236; called by muse, mutect2, varscan2
- ACMSD | c.537G>C p.Q179H | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, varscan2
- ACP3 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.029); called by muse, mutect2
- AFDN | c.4779C>G p.I1593M | Missense Mutation (SNP) | VAF 70/382 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CDH2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPN1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CPNE1 | c.1375G>T p.E459* (on ENST00000352393; = p.E464* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 123/524 reads (23%) | called by muse, mutect2, varscan2
- DAAM1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 107/456 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DCAF12L2 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 50/839 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH14 | c.9598G>C p.E3200Q (on ENST00000445597; = p.E4208Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP21 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 211/703 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- E2F5 | c.863C>T p.S288L | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- FAT1 | c.13522G>C p.E4508Q | Missense Mutation (SNP) | VAF 94/402 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FGB | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- FSIP2 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 35/143 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2
- GOLM1 | c.447G>C p.E149D | Missense Mutation (SNP) | VAF 78/314 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GPR158 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- GPR37 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 185/633 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDE | c.1043C>G p.S348* | Nonsense Mutation (SNP) | VAF 27/213 reads (13%) | called by muse, mutect2, varscan2
- IRF8 | c.508_509insCCTGCG p.R170delinsPCG | In Frame Ins (INS) | VAF 68/329 reads (21%) | called by mutect2, pindel, varscan2
- JAKMIP1 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.418); called by muse, mutect2
- KLHL28 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LCA5 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LZTFL1 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- MEGF8 | c.1478C>T p.S493L | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MUSK | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NCAM2 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 76/573 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR52B4 | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2
- PDGFB | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PGM3 | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PPEF1 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PSMD1 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PTPRC | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- RBM20 | c.3241C>G p.P1081A | Missense Mutation (SNP) | VAF 334/780 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RPS15 | c.233C>A p.T78K | Missense Mutation (SNP) | VAF 108/1014 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SCN9A | c.5827C>T p.P1943S (on ENST00000303354; = p.P1932S on NM_002977.3) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- TNKS2 | c.2132G>C p.G711A | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRPM7 | c.1305+1G>C p.X435_splice | Splice Site (SNP) | VAF 30/108 reads (28%) | called by mutect2, varscan2
- UGT2B11 | c.1572G>C p.K524N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZC3H11B | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 74/581 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZNF195 | c.739C>G p.Q247E (on ENST00000399602 / NM_001130520.3; = p.Q175E on NM_007152.5) | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.029); called by muse, mutect2
- ADGRD2 | c.2278C>T p.L760= | Silent (SNP) | VAF 109/456 reads (24%) | called by muse, mutect2, varscan2
- BBS4 | c.267C>G p.L89= | Silent (SNP) | VAF 56/298 reads (19%) | called by muse, mutect2, varscan2
- CBX4 | c.1275G>A p.K425= | Silent (SNP) | VAF 156/858 reads (18%) | called by muse, varscan2
- CREB3L1 | c.270G>A p.L90= | Silent (SNP) | VAF 120/490 reads (24%) | called by muse, mutect2, varscan2
- DDX3X | c.462C>T p.N154= (on ENST00000399959; = p.N155= on NM_001356.5) | Silent (SNP) | VAF 61/275 reads (22%) | catalogued as rs573700935; called by muse, mutect2, varscan2
- DOCK5 | c.4845G>A p.L1615= | Silent (SNP) | VAF 70/433 reads (16%) | catalogued as rs970434919; called by muse, mutect2, varscan2
- DYRK4 | c.1530C>T p.L510= | Silent (SNP) | VAF 99/339 reads (29%) | catalogued as COSV50544302; called by muse, mutect2, varscan2
- IL12A | c.687C>G p.L229= | Silent (SNP) | VAF 42/239 reads (18%) | called by muse, mutect2, varscan2
- ITIH1 | c.228C>G p.V76= | Silent (SNP) | VAF 77/446 reads (17%) | called by muse, mutect2, varscan2
- KITLG | c.297C>A p.S99= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- OR2T6 | c.807C>T p.I269= | Silent (SNP) | VAF 163/540 reads (30%) | catalogued as COSV63215964; called by muse, mutect2, varscan2
- PAPPA | c.2349C>G p.L783= | Silent (SNP) | VAF 109/493 reads (22%) | catalogued as rs769779469, COSV60287491; called by muse, mutect2, varscan2
- PCLO | c.2817C>T p.F939= | Silent (SNP) | VAF 75/337 reads (22%) | catalogued as rs776553494; called by muse, mutect2, varscan2
- PRKDC | c.9687C>G p.S3229= | Silent (SNP) | VAF 132/443 reads (30%) | called by muse, mutect2, varscan2
- RELN | c.2346G>C p.L782= | Silent (SNP) | VAF 80/336 reads (24%) | called by muse, mutect2, varscan2
- SCN1A | c.4083C>T p.F1361= (on ENST00000303395 / NM_001202435.3; = p.F1350= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/278 reads (17%) | called by muse, mutect2, varscan2
- ZNF33A | c.324C>T p.I108= (on ENST00000458705 / NM_006974.3; = p.I109= on NM_006954.2) | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs1231563880; called by muse, mutect2, varscan2
- MYBPC1 | c.3413-1741C>G | Intron (SNP) | VAF 33/211 reads (16%) | called by muse, mutect2, varscan2
